Somatic mutation profile of cancer-model specimen HCM-BROD-0922-C71-85A (Adherent Cell Line, passage 5; aliquot HCM-BROD-0922-C71-85A-01D-A88G-36), derived from the primary tumor of HCMI case HCM-BROD-0922-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.2 years (17,986 days).
Specimen HCM-BROD-0922-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cef2dea1-d483-40ee-967a-d1512c31eb5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0922-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0922-C71-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bc6cfaf-ba90-4386-b0ac-67d5615dbd09

The open-access MAF lists 54 somatic variants for this specimen: 36 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, 3'Flank 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1, In Frame Ins 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYF6 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 207/446 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.742); catalogued as rs747205109, COSV57353234; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTBL2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 188/367 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.085); catalogued as rs1301548159; called by muse, varscan2
- ARAP3 | c.2215G>A p.G739S | Missense Mutation (SNP) | VAF 152/316 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs771631565; called by muse, mutect2, varscan2
- CACNA1E | c.4762C>T p.R1588C | Missense Mutation (SNP) | VAF 165/351 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100701337; called by muse, mutect2, varscan2
- CBFA2T3 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 321/627 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs745881689, COSV99241221; called by muse, mutect2, varscan2
- DNAH1 | c.4472C>T p.A1491V | Missense Mutation (SNP) | VAF 182/358 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs369943421, COSV70226407; called by muse, mutect2, varscan2
- DNAH9 | c.7409G>A p.R2470Q | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs140586111, COSV52376541, COSV99303938; called by muse, mutect2, varscan2
- DPY19L2 | c.1359+1G>A p.X453_splice | Splice Site (SNP) | VAF 75/158 reads (47%) | catalogued as COSV60543995; called by muse, mutect2, varscan2
- GALNT14 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 146/380 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs377585928; called by muse, mutect2, varscan2
- GJB3 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 209/451 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs748539985; called by muse, mutect2, varscan2
- IGF2BP1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 162/383 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs1332823704; called by muse, mutect2, varscan2
- NOS1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 195/409 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1296555410, COSV100500727, COSV100501657; called by muse, mutect2, varscan2
- OBSCN | c.5291G>A p.R1764Q | Missense Mutation (SNP) | VAF 298/571 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as rs747573720; called by muse, mutect2, varscan2
- OR10H1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.337); catalogued as rs1169187924, COSV58473385; called by muse, mutect2, varscan2
- OR10H2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 167/828 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.226); catalogued as rs377347932; called by muse, mutect2, varscan2
- OR2A42 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs769489686; called by mutect2, varscan2
- OR5J2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 112/236 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748141067, COSV104394843, COSV56620700; called by muse, mutect2, varscan2
- PHLDB2 | c.3502G>T p.D1168Y (on ENST00000393925 / NM_001134439.2; = p.D1125Y on NM_145753.2) | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182878056, COSV67310233, COSV67312866; called by muse, mutect2, varscan2
- PKHD1L1 | c.10135G>T p.A3379S | Missense Mutation (SNP) | VAF 102/289 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV65744279; called by muse, mutect2, varscan2
- PRDM1 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64844620; called by muse, mutect2, varscan2
- PTEN | c.463T>A p.Y155N | Missense Mutation (SNP) | VAF 129/130 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123325, CM110152, CM132267, COSV64290082, COSV64307317; called by muse, mutect2, varscan2
- RFPL2 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 222/489 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.107); catalogued as rs1379803837, COSV99964399; called by muse, mutect2, varscan2
- RYR2 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 196/436 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754901791, COSV63712572; called by muse, mutect2, varscan2
- RYR3 | c.10634C>T p.T3545I (on ENST00000389232; = p.T3546I on NM_001036.6) | Missense Mutation (SNP) | VAF 159/314 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs550033490; called by muse, mutect2, varscan2
- TUBB8B | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 128/556 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs562881439; called by muse, varscan2
- CEP170B | c.1168C>T p.Q390* (on ENST00000453495; = p.Q319* on NM_015005.3) | Nonsense Mutation (SNP) | VAF 286/567 reads (50%) | called by muse, mutect2, varscan2
- DEPDC7 | c.1421A>G p.N474S (on ENST00000241051 / NM_001077242.2; = p.N465S on NM_139160.2) | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- KCNN2 | c.1549_1550del p.L517Dfs*3 (on ENST00000264773; = p.L729Dfs*3 on NM_021614.4) | Frame Shift Del (DEL) | VAF 129/416 reads (31%) | called by mutect2, pindel, varscan2
- MTCH1 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKTR | c.3329A>C p.H1110P | Missense Mutation (SNP) | VAF 108/232 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC4 | c.1500A>C p.E500D | Missense Mutation (SNP) | VAF 107/493 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OR1R1P | c.747_748insGTGGTG p.A249_L250insVV | In Frame Ins (INS) | VAF 149/325 reads (46%) | called by mutect2, varscan2
- OR51A2 | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 178/187 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, varscan2
- RBMY1J | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- TASP1 | c.294T>A p.F98L | Missense Mutation (SNP) | VAF 76/167 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF605 | c.879A>C p.K293N | Missense Mutation (SNP) | VAF 159/321 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABLIM3 | c.1449G>A p.S483= | Silent (SNP) | VAF 179/377 reads (47%) | catalogued as rs563171577, COSV58639195; called by muse, mutect2, varscan2
- ADAMTS12 | c.534C>T p.P178= | Silent (SNP) | VAF 175/352 reads (50%) | catalogued as rs369582749; called by muse, mutect2, varscan2
- ADAMTS2 | c.1938C>T p.H646= | Silent (SNP) | VAF 178/366 reads (49%) | catalogued as rs867867813; called by muse, mutect2, varscan2
- FAM98C | c.933C>T p.N311= | Silent (SNP) | VAF 138/308 reads (45%) | catalogued as rs745545912, COSV53038483; called by muse, varscan2
- FLG | c.2523T>A p.I841= | Silent (SNP) | VAF 170/395 reads (43%) | called by muse, mutect2, varscan2
- GALNT16 | c.1086C>A p.T362= | Silent (SNP) | VAF 134/251 reads (53%) | called by muse, mutect2, varscan2
- HMGCS2 | c.294C>G p.V98= | Silent (SNP) | VAF 198/403 reads (49%) | called by muse, mutect2, varscan2
- KANK1 | c.2781A>G p.Q927= | Silent (SNP) | VAF 176/342 reads (51%) | called by muse, mutect2, varscan2
- KRTAP9-6 | c.306G>A p.G102= | Silent (SNP) | VAF 29/439 reads (7%) | called by muse, mutect2
- MUC16 | c.312G>A p.S104= | Silent (SNP) | VAF 131/248 reads (53%) | catalogued as rs375785587; called by muse, mutect2, varscan2
- PKHD1 | c.4770C>A p.L1590= | Silent (SNP) | VAF 140/316 reads (44%) | catalogued as COSV100580976; called by muse, mutect2, varscan2
- SIGLEC1 | c.4975C>T p.L1659= | Silent (SNP) | VAF 178/339 reads (53%) | called by muse, mutect2, varscan2
- SMC1B | c.2010G>A p.E670= | Silent (SNP) | VAF 130/291 reads (45%) | catalogued as rs766630772; called by muse, mutect2, varscan2
- TAS2R39 | c.321C>T p.D107= | Silent (SNP) | VAF 130/620 reads (21%) | catalogued as rs565607872; called by muse, mutect2, varscan2
- TTN | c.84213C>T p.N28071= (on ENST00000591111; = p.N20647= on NM_003319.4) | Silent (SNP) | VAF 288/484 reads (60%) | catalogued as rs376289479; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- ZNF467 | c.399G>A p.A133= | Silent (SNP) | VAF 241/1120 reads (22%) | catalogued as COSV57372884; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1175G>A | Intron (SNP) | VAF 63/587 reads (11%) | catalogued as rs757844138, COSV63752762; called by muse, mutect2, varscan2
- LCORL | chr4:17876298 C>T | 3'Flank (SNP) | VAF 141/302 reads (47%) | called by muse, mutect2, varscan2
